Somatic mutation profile of tumor specimen TARGET-10-PAREYW-09A (aliquot TARGET-10-PAREYW-09A-01D) from TARGET case TARGET-10-PAREYW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.2 years (6,267 days).
Specimen TARGET-10-PAREYW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 652fefba-f8c9-4a37-88e7-9aa7ef48e092.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREYW-14A (Bone Marrow Normal), aliquot TARGET-10-PAREYW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1079702b-d52a-4f95-88c1-8d98e8bbed67

The open-access MAF lists 21 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 5, Intron 5, Frame Shift Ins 2, 5'Flank 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM21 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs775142915, COSV50791693; called by muse, mutect2, varscan2
- ARHGAP20 | c.630+1G>A p.X210_splice | Splice Site (SNP) | VAF 39/76 reads (51%) | catalogued as rs1449319024, COSV52814832; called by muse, mutect2, varscan2
- DPT | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs754102623, COSV63190323; called by muse, mutect2, varscan2
- FLT3 | c.1727T>C p.L576P | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV54047457, COSV54049031, COSV54049919; called by muse, mutect2, varscan2
- TTN | c.67742C>A p.P22581H (on ENST00000591111; = p.P15157H on NM_003319.4) | Missense Mutation (SNP) | VAF 37/76 reads (49%) | PolyPhen probably damaging (0.912); catalogued as COSV60187000; called by muse, mutect2, varscan2
- KMT2D | c.8065_8066insCAGTC p.L2689Pfs*4 | Frame Shift Ins (INS) | VAF 5/46 reads (11%) | called by mutect2, pindel
- WDFY4 | c.6524dup p.L2175Ffs*4 | Frame Shift Ins (INS) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- ADAMDEC1 | c.897G>T p.G299= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs141164035, COSV56474281, COSV56476253; called by muse, mutect2
- C16orf95 | c.378G>C p.A126= (on ENST00000253461 / NM_001195125.2; = p.G188R on NM_001195124.3) | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs780555091, COSV53678776; called by muse, mutect2, varscan2
- FNDC3B | c.714C>T p.S238= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as rs151151218, COSV61045789; called by muse, mutect2, varscan2
- KMT2D | c.5160G>A p.V1720= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV56462139; called by muse, mutect2, varscan2
- MAP2 | c.813G>A p.T271= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs147274334, COSV99562024; called by muse, mutect2, varscan2
- SGO1 | c.750G>A p.K250= | Silent (SNP) | VAF 13/131 reads (10%) | called by muse, mutect2, varscan2
- AC245128.1 | n.1084C>T | RNA (SNP) | VAF 30/63 reads (48%) | catalogued as rs1340007339; called by muse, mutect2, varscan2
- ADGRG3 | c.492+31T>G | Intron (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505989 G>T | 5'Flank (SNP) | VAF 51/117 reads (44%) | called by muse, mutect2, varscan2
- JADE1 | c.1503+64G>A | Intron (SNP) | VAF 22/34 reads (65%) | catalogued as rs762495492, COSV56907825; called by muse, mutect2, varscan2
- MCTP2 | c.1891-196C>T | Intron (SNP) | VAF 12/26 reads (46%) | catalogued as rs565502478; called by muse, varscan2
- MTA3 | c.1759+46T>C | Intron (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- SEC63 | c.1936-108G>T | Intron (SNP) | VAF 4/26 reads (15%) | catalogued as rs1179690928; called by muse, mutect2
